Surgical pathology report (de-identified scan), TCGA case TCGA-XK-AAJA, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-XK-AAJA-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

****ADDENDUM PRESENT****

Patient Name: [REDACTED]
Clinic Number: [REDACTED]
Date of Birth: [REDACTED] Age: [REDACTED] Gender: M
Requested By: [REDACTED]

Accession #: [REDACTED]
Procedure Date: [REDACTED]
Received Date: [REDACTED]
Account #: [REDACTED]
Report Signed: [REDACTED]

Final Diagnosis:

Robotic-assisted radical prostatectomy and bilateral pelvic lymph node dissection.

A-D. Four separate biopsies of margins labeled anterior bladder neck margin, right lateral bladder neck margin, left lateral bladder neck margin, and posterior prostate margin: All four specimens consist predominately of fibromuscular and fibroadipose tissue, and are negative for carcinoma.

E. Prostate with bilateral nodes. Synoptic report.

Procedure: Robotic-assisted radical prostatectomy, bilateral pelvic lymph node dissection.

Histologic type: Adenocarcinoma, acinar type.

Histologic grade: Primary pattern: 4 Secondary pattern: 3 Total Gleason Score: 7

Tumor quantitation: Multifocal bilateral infiltrating adenocarcinoma. The bulk of the tumor is on left side, involves apex, midgland, and base, and measures at least 3 cm in greatest dimension. There are separate foci of carcinoma present on the right side, Gleason grade 3+4 and 3+3 varying from 7 mm down to less than 3 mm. Carcinoma involves more than 5%, but less than 50%, of total prostatic volume.

Extraprostatic extension: Present on the left side, in mid gland and at base (reviewed with Dr

Margins: All surgical margins are negative for carcinoma.

Lymph-vascular invasion: Present.

Perineural invasion: Present.

Seminal vesicle invasion: Absent.

Treatment effect on carcinoma: Not applicable.

Lymph nodes: Seven pelvic lymph nodes negative for carcinoma, 0/7.

Additional pathologic findings: High grade prostatic intraepithelial neoplasia.

Ancillary studies: Paraffin-embedded tumor tissue (block E9) will be sent for DNA ploidy studies; AN
ADDENDUM WILL BE ISSUED.

Pathologic staging: pT3.

Biorepository sample (if applicable): The mirror image section consists entirely of invasive carcinoma.

Interpreted by:

Report electronically signed out by

Transcribed by:

ADDENDA:

Paraffin embedded tumor tissue was sent to

for DNA ploidy by

The report

Page 1 of 3

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
Q10 3/25/14

[page 2 of 4]
[REDACTED]
[REDACTED]
; interpreted by

) follows:

Source: Prostate, Robotic-Assisted Radical Prostatectomy, block

E9

Results:

The cancer cells are DNA aneuploid.

DIA ploidy test results have been validated by our laboratory for formalin-fixed, paraffin embedded tissue sections. Analysis was performed using the instrument which determined DNA ploidy status by comparing the DNA content of tumor cells and control cells (selected by operator). This test was developed and its performance characteristics determined by [REDACTED] This test has not been cleared or approved by the U.S. Food and Drug Administration.

Proliferation index (MIB-1) = 5.50%.

KI-67 Antigen immunohistochemical test results have been validated by our laboratory for paraffin embedded tissue sections fixed in formalin. Testing is performed using the MIB-1 clone and a polymer-based detection system. All controls show appropriate reactivity. Image collection and analysis is performed using the instrument. The renders the percentage of positive staining tumor nuclei (tumor selected by operator). This test was developed and its performance characteristics determined by [REDACTED] This test has not been cleared or approved by the U.S. Food and Drug Administration.

Transcribed by

Signed by

Clinical Information:

Prostate cancer.

Specimen(s):

- A: Anterior bladder neck margin
- B: Right lateral bladder neck margin
- C: Left lateral bladder neck margin
- D: Posterior prostate margin
- E: Prostate with bilateral lymph nodes

Preliminary Intraoperative Diagnosis:

Intraoperative Pathologist(s):

- A. Bladder neck anterior margin, frozen section diagnosis: Smooth muscle, no glands, no malignancy.
- B. Right lateral bladder neck margin, frozen section diagnosis: Smooth muscle, no glands, no malignancy.
- C. Left lateral bladder neck margin, frozen section diagnosis: Smooth muscle, no glands, no malignancy.
- D. Posterior prostate margin biopsy, frozen section diagnosis: Negative for carcinoma.

Gross Description:

Performed by

Pathologist's Assistant

A1B1C1D1E1E2E3E4E5E6E7E8E9E10E11E12E13E14E15E16E17E18E19

- A. Received fresh labeled [REDACTED] and "anterior bladder neck margin" are two tan tissue fragments, 0.3 cm in maximum dimension. Entirely submitted for frozen section in one cassette labeled A1.

[page 3 of 4]
- B. Received fresh labeled [REDACTED] and "right lateral bladder neck margin" is a 0.9 cm tan tissue fragment. Entirely submitted for frozen section in one cassette labeled B1.
- C. Received fresh labeled [REDACTED] and "left lateral bladder neck margin" are two gray-tan tissue fragments, 0.5 and 0.6 cm in maximum dimension. Entirely submitted for frozen section in one cassette labeled C1.
- D. Received fresh labeled [REDACTED] and "posterior prostate margin" is a piece of soft tissue, 0.4 x 0.4 x 0.4 cm. Entirely submitted for frozen section in one cassette labeled D1.
- E. Received fresh labeled [REDACTED] and "prostate with bilateral pelvic lymph nodes."

Procedure: Radical prostatectomy.

Prostate size: Weight: 56 grams; Dimensions: 4 x 3.8 x 3.8 cm; Seminal vesicles: 3 x 2 x 1.2 cm.

Gross notes: Grossly evident tumor: Yes, 1.2 x 1 x 0.9 cm in the left apex-mid portion of the specimen.

Symmetry: Asymmetric. The left appears somewhat larger than the right.

Gross nodular hyperplasia: Mild.

Gross capsular bulge/defect: There is a slight bulging of the left mid-apex capsule.

Inking: left-black, right-blue

Lymph nodes: Pelvic lymph nodes are present in adipose tissue aggregating to 5 x 4 x 1.2 cm. Within the adipose tissue multiple lymph nodes are identified.

Block summary for specimen E:

- 1) proximal urethral margin
- 2) distal urethral margin
- 3) left apical margin
- 4) right apical margin
- 5) left bladder neck margin
- 6) right bladder neck margin
- 7) left apical prostate
- 8) right apical prostate
- 9) left mid prostate
- 10) right mid prostate
- 11) left mid prostate
- 12) right mid prostate
- 13) left base of prostate
- 14) right base of prostate
- 15) left seminal vesicle
- 16) right seminal vesicle
- 17) mirror image of tissue corresponding to research
- 18) three possible fatty lymph nodes.
- 19) two possible fatty lymph nodes.

*Per dx discrepancy form, TCGA
tumor is Gleason 4+4.*

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by [REDACTED]. They have not been cleared or approved by the U. S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Primary 4 Secondary 3 Total 7	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Primary 4 Secondary 4 Total 8	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	During Path review it was determined gleason score on Path report is different than TCGA sample gleason score determined by	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file c065aaa4-1bb0-4441-b88d-7e9d6fb3163d (TCGA-XK-AAJA.C7BDC09C-7947-4F71-A2CE-4FED7D9C515B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).